Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5495, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5495-01A (Primary Tumor).

The patient is a [REDACTED]
He underwent a prostate needle biopsy [REDACTED] demonstrating prostatic
adenocarcinoma, with a maximal Gleason score $4 + 4 = 8$.
PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical retropubic prostatectomy and bilateral pelvic lymph node dissection.

FINAL DIAGNOSIS:

TCGA-EJ-5495

PART 1: RIGHT PELVIC LYMPH NODES, EXCISION -

- A. MICROSCOPIC FOCUS OF METASTATIC PROSTATIC ADENOCARCINOMA LARGELY REPLACING ONE OF NINE (1/9) LYMPH NODES (SLIDE 1C).
- B. METASTATIC FOCUS MEASURES 0.15 CM.
- C. NO EXTRACAPSULAR EXTENSION IS IDENTIFIED (See comment).

PART 2: LEFT PELVIC LYMPH NODES, EXCISION -

- NINE BENIGN LYMPH NODES (0/9). NO EVIDENCE OF MALIGNANCY.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES, AND BILATERAL DISTAL VASA DEFERENTIA (RADICAL PROSTATECTOMY) -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE WITH FOCAL ONCOCYTIC AND FOCAL SIGNET RING CELL FEATURES, GLEASON SCORE $5 + 3 = 8$ WITH A TERTIARY GLEASON PATTERN 4 CARCINOMA COMPONENT. GLEASON PATTERNS 4 AND 5 COMPONENTS COMPRISE APPROXIMATELY 75% OF THE EXAMINED TUMOR VOLUME. CARCINOMA EXTENSIVELY INVOLVES BOTH RIGHT AND LEFT LOBES OF THE PROSTATE GLAND.
- B. MAXIMAL TUMOR DIAMETER IS 2.3 CM IN A HISTOLOGIC SECTION.
- C. CARCINOMA COMPRISES APPROXIMATELY 40% OF THE EXAMINED PROSTATE GLAND VOLUME.
- D. MULTIFOCAL ESTABLISHED EXTRACAPSULAR EXTENSION IS PRESENT IN THE FOLLOWING REGIONS: BILATERAL POSTERIOR BASE / PERISEMINAL VESICLE SOFT TISSUE (SECTIONS 3A, 3C, 3AA), BILATERAL ANTERIOR MID PROSTATE (SECTIONS 3N AND 3S), AND LEFT ANTERIOR BASE (SECTION 3T).
- E. EXTENSIVE CARCINOMATOUS PERINEURAL INVASION IS IDENTIFIED.
- F. SEVERAL MICROSCOPIC ANGIOLYMPHATIC TUMOR EMBOLI ARE IDENTIFIED (SECTIONS 3Q, 3T, 3RR, AND 3YY).
- G. CARCINOMA EXTENSIVELY INFILTRATES BILATERAL SEMINAL VESICLES (SECTIONS 3A AND 3C) AND RIGHT VAS DEFERENS (SECTION 3B).
- H. CARCINOMA IS PRESENT AT THE RIGHT VAS DEFERENS RESECTION MARGIN. MAXIMAL LINEAR EXTENT OF MARGIN POSITIVITY IS 0.3 CM. ALL OTHER SURGICAL RESECTION MARGINS SAMPLED ARE MICROSCOPICALLY FREE OF NEOPLASIA.
- I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA.
- J. NON-NEOPLASTIC PROSTATE WITH FOCAL GLANDULAR ATROPHY.
- K. TNM PATHOLOGIC STAGE: T3b, N1, MX.
- L. HISTOLOGIC GRADE: G3-4 (SEE COMMENT AND SYNOPSIS).

COMMENT:

Parts 1 and 3: One small lymph node is largely replaced by metastatic carcinoma (slide 1C), visible on the H&E stained section. The diagnosis of metastatic prostatic adenocarcinoma is supported to an immunohistochemical panel of stains, demonstrating that the metastatic carcinoma cells are immunoreactive for pankeratin, prostate specific antigen, and androgen receptor, and are negative for leukocyte common antigen and CD68. Cytokeratin immunostains performed on the other two right pelvic lymph nodes sections (slides 1A, 1B) are also performed, and show no occult metastatic foci in these lymph nodes. The overall pathologic N stage is N1.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 10.84
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS Signet ring adenocarcinoma
PRIMARY GLEASON GRADE:	5
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	75%
WEIGHT OF PROSTATE:	67.8gm
TUMOR SIZE:	Maximum dimension: 2.3 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Multifocal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	Focal tumor involvement at margin
LYMPH NODES EXAMINED:	18
LYMPH NODES POSITIVE:	1
EXTRANODAL EXTENSION:	No
SIZE OF NODAL METASTASIS:	1.5mm
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated
Comment:	Tertiary Gleason pattern 4 carcinoma component is present. Carcinoma involves the right vas deferens resection margin.

Source: NCI Genomic Data Commons file f72998f8-2e4a-41b6-94e8-a9d08ef7d704 (TCGA-EJ-5495.5C549C39-B223-49EB-AA93-0298CDF33370.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).